Somatic mutation profile of tumor specimen C3N-01893-02 (aliquot CPT0126450006) from CPTAC case C3N-01893, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 70.9 years (25,889 days).
Specimen C3N-01893-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d6ff59a-2a36-4959-b574-1d99f52f98b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01893-31 (Blood Derived Normal), aliquot CPT0126510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93a53e85-b345-41e2-ba2a-56bfb53eb9e4

The open-access MAF lists 621 somatic variants for this specimen: 401 protein-altering or splice-affecting, 152 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 338, Silent 152, Nonsense Mutation 34, Intron 26, RNA 10, 3'UTR 9, 5'UTR 9, Splice Region 8, 5'Flank 8, Frame Shift Del 8, Splice Site 7, 3'Flank 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5027G>A p.W1676* | Nonsense Mutation (SNP) | VAF 93/750 reads (12%) | catalogued as rs797045495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PYGM | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 57/506 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs119103253, CM951095; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 42/309 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACO2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.48); catalogued as rs1357717726; called by muse, mutect2
- ADAD1 | c.1469G>A p.S490N | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs757153184; called by muse, mutect2
- ADAMTS12 | c.3737A>G p.N1246S | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs373062449; called by muse, mutect2, varscan2
- ADAMTS12 | c.1848C>G p.Y616* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | catalogued as COSV61272626; called by muse, mutect2, varscan2
- ADGRB3 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV65415329; called by muse, mutect2, varscan2
- ADGRD2 | c.1157C>A p.A386E | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV58341845; called by muse, varscan2
- ADGRL4 | c.2047C>A p.P683T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.94); catalogued as rs759465075, COSV66066509; called by muse, mutect2, varscan2
- AGA | c.506G>T p.R169M | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV99219464; called by muse, varscan2
- AKAP9 | c.11329G>C p.E3777Q (on ENST00000359028; = p.E3753Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV100663401; called by muse, mutect2, varscan2
- ALG10 | c.1381C>G p.Q461E | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56793130; called by muse, mutect2, varscan2
- AP002748.5 | c.1221G>C p.P407= | Splice Region (SNP) | VAF 87/609 reads (14%) | catalogued as CS127324, COSV59149528; called by muse, mutect2, varscan2
- ARIH1 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as rs12902861; called by muse, varscan2
- ATP13A5 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100665594; called by muse, mutect2
- B4GALNT2 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs770770615; called by muse, mutect2, varscan2
- BBS9 | c.1965A>G p.L655= (on ENST00000242067 / NM_001348036.1; = p.L615= on NM_014451.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 22/287 reads (8%) | catalogued as COSV54177920; called by muse, mutect2
- BCAN | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.833); catalogued as rs537017904; called by muse, mutect2
- C1GALT1 | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1486027322, COSV56180422; called by muse, varscan2
- CACNA2D1 | c.2533A>C p.S845R (on ENST00000356253 / NM_001366867.1; = p.S833R on NM_000722.4) | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.701); catalogued as COSV62395465; called by muse, mutect2, varscan2
- CACNA2D1 | c.2351G>T p.G784V (on ENST00000356253 / NM_001366867.1; = p.G772V on NM_000722.4) | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as COSV62373270; called by muse, mutect2
- CAMK2N2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 38/461 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as rs772874827, COSV99955611; called by muse, mutect2
- CAPRIN2 | c.2800A>G p.I934V | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as rs140741615; called by muse, mutect2, varscan2
- CCDC158 | c.1553A>T p.E518V | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101187191; called by muse, mutect2, varscan2
- CD163L1 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100550464; called by muse, mutect2, varscan2
- CDH9 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 43/417 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, mutect2, varscan2
- CDK16 | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52094368; called by muse, mutect2, varscan2
- CFAP46 | c.5080A>T p.R1694W | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV54152408; called by muse, mutect2
- CHD2 | c.2173C>G p.Q725E | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67708011; called by muse, mutect2
- CHST6 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 94/851 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1339761685; called by muse, mutect2, varscan2
- CHST7 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52099700; called by muse, mutect2, varscan2
- CNR1 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 27/335 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1202792871; called by muse, mutect2
- CNTN2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 38/651 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs200403900; called by muse, mutect2
- COL1A2 | c.2108G>C p.G703A | Missense Mutation (SNP) | VAF 96/745 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99799702; called by muse, mutect2, varscan2
- COL4A4 | c.2218C>G p.P740A | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV61634843; called by muse, mutect2, varscan2
- COX7A2L | c.72+6A>T | Splice Region (SNP) | VAF 70/546 reads (13%) | catalogued as rs371146473; called by muse, mutect2, varscan2
- DGKI | c.1948-2A>G p.X650_splice | Splice Site (SNP) | VAF 21/168 reads (13%) | catalogued as COSV55945512; called by muse, mutect2, varscan2
- DNAH17 | c.3484G>T p.E1162* | Nonsense Mutation (SNP) | VAF 24/196 reads (12%) | catalogued as COSV67757846; called by muse, mutect2, varscan2
- EEF1AKMT4 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs763608257, COSV56182176; called by muse, mutect2
- EIF3B | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 31/438 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as rs1343197759; called by muse, mutect2
- ERCC4 | c.2119G>C p.E707Q | Missense Mutation (SNP) | VAF 54/454 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV61311540; called by muse, mutect2, varscan2
- EWSR1 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100131474; called by muse, mutect2
- EXOC4 | c.62C>A p.S21* | Nonsense Mutation (SNP) | VAF 22/318 reads (7%) | catalogued as rs183280115, COSV54081769, COSV99555488; called by muse, mutect2
- EYA1 | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 59/494 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1213738374; called by muse, mutect2, varscan2
- FAM135B | c.3974G>T p.R1325M | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99419284; called by muse, mutect2, varscan2
- FBXL13 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as rs779469571; called by muse, mutect2, varscan2
- GAB1 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as COSV53761786; called by muse, mutect2
- GALNT17 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 43/376 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs759720103, COSV61152407; called by muse, mutect2, varscan2
- GBX2 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1415881160, COSV60445551; called by muse, mutect2
- GCFC2 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1173535348; called by muse, mutect2
- GDF15 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 71/520 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs1333809198; called by muse, mutect2, varscan2
- GNG2 | c.63G>T p.K21N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1046430721; called by muse, mutect2, varscan2
- GOLGA6L2 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 34/244 reads (14%) | catalogued as rs1472866797, COSV61485449; called by muse, mutect2, varscan2
- H4C12 | c.311G>C p.*104Sext*? | Nonstop Mutation (SNP) | VAF 7/116 reads (6%) | catalogued as COSV62743637, COSV62743749; called by muse, mutect2
- H6PD | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 69/515 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV66231465; called by muse, mutect2, varscan2
- HAUS5 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.266); catalogued as COSV52547167; called by muse, mutect2, varscan2
- HJV | c.451G>A p.E151K (on ENST00000336751 / NM_213653.4; = p.E38K on NM_145277.5) | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV60952121; called by muse, mutect2, varscan2
- HLA-B | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 53/463 reads (11%) | catalogued as rs137854653, CM1412111, COSV69520364, COSV69521019; called by muse, mutect2, varscan2
- IL27 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs762177584, COSV100795862; called by muse, mutect2
- KANK2 | c.2380G>A p.V794M (on ENST00000586659 / NM_001379562.1; = p.V802M on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/361 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs759430532, COSV62006296; called by muse, mutect2, varscan2
- KAT6A | c.5228G>C p.S1743T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs1239809357; called by muse, mutect2
- KAT6A | c.3462A>C p.K1154N | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD166937; called by muse, mutect2
- KCNA5 | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.379); catalogued as rs528221767, COSV52905536; called by muse, mutect2, varscan2
- KCNF1 | c.918C>A p.H306Q | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99705818; called by muse, mutect2, varscan2
- KCNH2 | c.1960A>G p.S654G | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as CM133173, CX097475; called by muse, mutect2
- KCNQ3 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.721); catalogued as rs1341626282, COSV66466683; called by muse, mutect2, varscan2
- KCNV1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.553); catalogued as COSV52087566; called by muse, mutect2, varscan2
- KLRD1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); catalogued as rs1381466136, COSV60273742; called by muse, mutect2
- KRTAP1-3 | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 56/461 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542205409; called by muse, mutect2, varscan2
- LAMA5 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1405665005; called by muse, mutect2, varscan2
- LIMA1 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV57968369; called by muse, mutect2, varscan2
- LPA | c.6047G>A p.R2016H | Missense Mutation (SNP) | VAF 49/409 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs369415160; called by muse, mutect2, varscan2
- LPXN | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.059); catalogued as COSV67717225; called by muse, mutect2
- LRRK2 | c.4165G>A p.V1389I | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs140743795; ClinVar: uncertain significance; called by muse, mutect2
- LYPLA1 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 29/233 reads (12%) | catalogued as rs750847085; called by muse, mutect2, varscan2
- MAEL | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs202037854, COSV63304212; called by muse, mutect2, varscan2
- MBD1 | c.1015G>A p.G339R (on ENST00000269468 / NM_001323950.1; = p.G316R on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282509795; called by muse, mutect2
- MCRIP1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1367987404; called by muse, mutect2, varscan2
- MDC1 | c.5870G>T p.R1957L | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV64524194; called by muse, mutect2, varscan2
- MED1 | c.3686C>T p.S1229F | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as rs1567637769; called by muse, mutect2, varscan2
- MEF2C | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV60930253; called by muse, mutect2
- MMP16 | c.1398G>T p.M466I | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1323199288, COSV54181118; called by muse, mutect2
- MYO9B | c.4735G>A p.E1579K | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.363); catalogued as COSV101261208, COSV68282552; called by muse, mutect2, varscan2
- NANP | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.792); catalogued as rs758394305, COSV100505060; called by muse, mutect2, varscan2
- NDST4 | c.2530G>C p.D844H | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as rs1489438362; called by muse, mutect2
- NRG3 | c.163A>G p.S55G | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs751623257; called by muse, mutect2, varscan2
- OBI1 | c.368A>T p.Q123L | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV56144505; called by muse, mutect2, varscan2
- OR2A14 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 54/455 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV68718084; called by muse, mutect2, varscan2
- OR2L3 | c.923G>T p.C308F | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1362087571; called by muse, mutect2, varscan2
- OR2M2 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.02); catalogued as COSV62898689; called by muse, mutect2, varscan2
- OR4N2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs763828281, COSV60055727; called by muse, mutect2
- PLA2G15 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.691); catalogued as COSV99547168; called by muse, mutect2
- PLCB1 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 7/157 reads (4%) | catalogued as rs990536521, COSV62069479; called by muse, mutect2
- PNPLA8 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs757146153; called by muse, mutect2, varscan2
- PPFIA4 | c.2172G>A p.K724= (on ENST00000447715; = p.K725= on NM_001304331.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 52/183 reads (28%) | catalogued as COSV99690952; called by muse, mutect2, varscan2
- PRB4 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.623); catalogued as COSV54400833; called by muse, mutect2, varscan2
- PREPL | c.129G>T p.L43F | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.829); catalogued as rs779251130; called by muse, mutect2, varscan2
- PSD4 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1254329837; called by muse, mutect2
- PSMC4 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.006); catalogued as COSV50094420, COSV50098231; called by muse, mutect2, varscan2
- PTPRD | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 9/184 reads (5%) | catalogued as COSV61929162; called by muse, mutect2
- RAB6B | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 28/213 reads (13%) | catalogued as rs775065498; called by muse, mutect2, varscan2
- RAX | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1357553942; called by muse, mutect2, varscan2
- RIPK3 | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs1297570495; called by muse, mutect2, varscan2
- ROBO2 | c.1301C>G p.T434R | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59903793; called by muse, mutect2, varscan2
- RTP5 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs775542991; called by muse, mutect2, varscan2
- RYR1 | c.3491A>G p.N1164S | Missense Mutation (SNP) | VAF 187/720 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1193678705; called by muse, mutect2, varscan2
- SCAF1 | c.2053del p.A685Pfs*53 | Frame Shift Del (DEL) | VAF 17/125 reads (14%) | catalogued as rs1377517037; called by mutect2, pindel, varscan2
- SEPTIN14 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 107/460 reads (23%) | catalogued as rs748203186, COSV101193393; called by muse, mutect2, varscan2
- SHANK1 | c.4547C>G p.P1516R | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.549); catalogued as rs1243658794; called by muse, mutect2, varscan2
- SIX3 | c.580C>A p.R194S | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99578552; called by muse, mutect2
- SLC25A1 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 75/527 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as rs782121656; called by muse, mutect2, varscan2
- SLC26A1 | c.272C>G p.S91* | Nonsense Mutation (SNP) | VAF 27/172 reads (16%) | catalogued as COSV56101993; called by muse, mutect2, varscan2
- SLC34A1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1261946494; called by muse, mutect2, varscan2
- SLC36A4 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.071); catalogued as rs749640932; called by muse, mutect2, varscan2
- SLFN13 | c.1928G>C p.R643T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV53193854; called by muse, mutect2
- SLU7 | c.1405T>A p.C469S | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV51789074; called by muse, mutect2, varscan2
- SMARCA4 | c.3156C>G p.F1052L | Missense Mutation (SNP) | VAF 75/605 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60785603; called by muse, mutect2, varscan2
- SOGA1 | c.4113G>C p.Q1371H | Missense Mutation (SNP) | VAF 48/374 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52914388; called by muse, mutect2, varscan2
- SORCS3 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1485955556; called by muse, mutect2
- SORCS3 | c.3070G>A p.D1024N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63794607; called by muse, mutect2, varscan2
- SOX10 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as rs1431927888, COSV62806560; called by muse, mutect2
- SPARCL1 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372976612, COSV99215711; called by muse, mutect2, varscan2
- SPTB | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 65/346 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs775936031; called by muse, mutect2, varscan2
- SPTBN2 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 30/475 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV59454415; called by muse, mutect2
- SRCAP | c.8592del p.K2865Rfs*21 | Frame Shift Del (DEL) | VAF 16/96 reads (17%) | catalogued as COSV52675610; called by mutect2, pindel, varscan2
- STEAP3 | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 62/580 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100713419; called by muse, mutect2, varscan2
- STOML1 | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.342); catalogued as rs747932881, COSV51450999; called by muse, varscan2
- SYNE1 | c.5311G>C p.D1771H (on ENST00000367255 / NM_182961.4; = p.D1778H on NM_033071.3) | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99576339; called by muse, mutect2
- TCFL5 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs763542036, COSV53896203; called by muse, mutect2, varscan2
- TET2 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 16/125 reads (13%) | catalogued as COSV54400736; called by muse, mutect2, varscan2
- THSD7A | c.2505G>A p.W835* | Nonsense Mutation (SNP) | VAF 26/240 reads (11%) | catalogued as COSV101448646; called by muse, mutect2
- TMEM132B | c.2325G>C p.K775N | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs767664445; called by muse, mutect2, varscan2
- TMEM232 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as rs1430173425, COSV70273877; called by muse, mutect2, varscan2
- TRIM68 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1249565978; called by muse, mutect2, varscan2
- TYR | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.722); catalogued as CM941342; called by muse, mutect2, varscan2
- UBQLN2 | c.1503A>G p.I501M | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.192); catalogued as rs1375406617; called by muse, mutect2, varscan2
- UNC13C | c.3582G>C p.Q1194H | Missense Mutation (SNP) | VAF 19/303 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1255343615, COSV52926307; called by muse, mutect2
- UNC13C | c.4397C>A p.S1466* | Nonsense Mutation (SNP) | VAF 20/146 reads (14%) | catalogued as COSV99511938; called by muse, mutect2
- UROD | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1204882356; called by muse, mutect2, varscan2
- USP42 | c.191C>G p.S64W | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201800019, COSV100083812; called by muse, mutect2, varscan2
- XAB2 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1289968515; called by muse, mutect2, varscan2
- XKR7 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374398061; called by muse, mutect2, varscan2
- YEATS2 | c.1690C>T p.L564F | Missense Mutation (SNP) | VAF 23/352 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV100528414; called by muse, mutect2
- ZC3H11A | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100142974; called by muse, mutect2
- ZC3H13 | c.4402G>A p.E1468K (on ENST00000242848 / NM_001330565.2; = p.E1469K on NM_015070.6) | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV54450231; called by muse, mutect2
- ZFHX4 | c.8150C>T p.T2717I | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs752747502, COSV50831743; called by muse, mutect2
- ZNF189 | c.902C>A p.S301* | Nonsense Mutation (SNP) | VAF 13/152 reads (9%) | catalogued as COSV52274465; called by muse, mutect2
- ZNF391 | c.584G>T p.C195F | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180576639; called by muse, varscan2
- ZNF431 | c.734C>G p.S245* | Nonsense Mutation (SNP) | VAF 20/159 reads (13%) | catalogued as COSV60673783; called by muse, mutect2, varscan2
- ZNF486 | c.1292A>G p.E431G | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs373974754; called by muse, varscan2
- ZNF658 | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs1454831700; called by muse, mutect2, varscan2
- ABCA10 | c.1967A>T p.K656I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- ABCA12 | c.7387G>T p.V2463L (on ENST00000272895 / NM_173076.3; = p.V2145L on NM_015657.3) | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ABCA5 | c.502T>A p.Y168N | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- AC063943.2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ADNP2 | c.2739C>G p.F913L | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- AFG3L2 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- ALDH3B1 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- ANKRD17 | c.1618C>G p.L540V | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AP4B1 | c.1817A>T p.K606M | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- APC | c.1566G>C p.M522I | Missense Mutation (SNP) | VAF 63/329 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- APOB | c.5501A>G p.N1834S | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- APOBEC1 | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOLD1 | c.426C>G p.F142L (on ENST00000326765 / NM_001130415.2; = p.F111L on NM_030817.3) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ARHGEF17 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2
- AXL | c.1730C>G p.S577* (on ENST00000301178 / NM_021913.5; = p.S568* on NM_001699.6) | Nonsense Mutation (SNP) | VAF 33/242 reads (14%) | called by muse, mutect2, varscan2
- BCL11A | c.2021G>C p.G674A (on ENST00000335712 / NM_001365609.1; = p.G708A on NM_018014.4) | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); called by muse, mutect2
- BCL6 | c.821A>T p.H274L | Missense Mutation (SNP) | VAF 51/399 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf120 | c.654T>A p.H218Q | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- C16orf72 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- C4orf54 | c.2071G>T p.G691C | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- C7 | c.2138G>T p.C713F | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CA5A | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- CACNA1A | c.7093C>A p.H2365N | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CAD | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMK4 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CATSPERD | c.1284G>T p.M428I | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CBX4 | c.1400C>G p.S467* | Nonsense Mutation (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- CCDC168 | c.3619G>C p.E1207Q | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.543); called by muse, mutect2
- CCDC172 | c.242G>C p.S81T | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC88C | c.5002G>C p.E1668Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CD96 | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.247); called by muse, mutect2
- CDH4 | c.1051-1G>C p.X351_splice | Splice Site (SNP) | VAF 18/94 reads (19%) | called by muse, varscan2
- CDH7 | c.1790A>T p.E597V | Missense Mutation (SNP) | VAF 51/414 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEMIP2 | c.1648C>G p.H550D | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CENPE | c.4015G>C p.E1339Q | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.366); called by muse, mutect2
- CERS6 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP65 | c.5557C>A p.L1853I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CFAP65 | c.2824C>A p.L942M | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CFD | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFHR4 | c.764A>T p.N255I (on ENST00000367416 / NM_001201551.2; = p.N256I on NM_001201550.3) | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- CHCHD2 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 40/397 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.531); called by muse, varscan2
- CLDN3 | c.465G>C p.Q155H | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CLN3 | c.884A>T p.Y295F (on ENST00000360019 / NM_001286104.2; = p.Y319F on NM_000086.2) | Missense Mutation (SNP) | VAF 79/543 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COG5 | c.2085T>G p.Y695* (on ENST00000347053 / NM_001379512.1; = p.Y716* on NM_006348.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 28/242 reads (12%) | called by muse, mutect2, varscan2
- COL6A5 | c.168G>C p.M56I | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CPN1 | c.572G>T p.S191I | Missense Mutation (SNP) | VAF 19/285 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2
- CPNE2 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2
- CTAGE8 | c.1967C>G p.S656* | Nonsense Mutation (SNP) | VAF 30/290 reads (10%) | called by muse, mutect2
- CTNNA2 | c.1538C>G p.S513* | Nonsense Mutation (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2
- CXXC4 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- DAAM1 | c.3090C>A p.S1030R | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- DDX6 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 9/260 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.096); called by muse, mutect2
- DENND2A | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DHPS | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- DNAJA2 | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DNAJC10 | c.1077+2T>G p.X359_splice | Splice Site (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- DNAJC13 | c.2806A>T p.I936L | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- DSC2 | c.1793A>T p.D598V | Missense Mutation (SNP) | VAF 33/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- DSC2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); called by muse, mutect2
- DSC3 | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.02); called by muse, mutect2
- DST | c.8668G>A p.E2890K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DTX2 | c.304_305insT p.Q102Lfs*24 | Frame Shift Ins (INS) | VAF 27/183 reads (15%) | called by mutect2, pindel
- EGR1 | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- EIF2A | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHA1 | c.1481A>G p.Q494R | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- EPHA10 | c.626A>T p.K209M | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHB4 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 90/602 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- EPHX3 | c.75G>C p.W25C | Missense Mutation (SNP) | VAF 72/548 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ERBB2 | c.2725+7G>A | Splice Region (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- ETV3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- FAM171B | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, varscan2
- FAM47A | c.1927A>T p.K643* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- FAT1 | c.1190_1197del p.H397Lfs*4 | Frame Shift Del (DEL) | VAF 18/149 reads (12%) | called by mutect2, pindel, varscan2
- FCER2 | c.333G>C p.W111C | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.57); called by muse, mutect2
- FER1L5 | c.1049A>G p.D350G (on ENST00000623019; = p.D367G on NM_001293083.2) | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FKTN | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 17/216 reads (8%) | called by muse, mutect2
- FOXA2 | c.583T>G p.F195V (on ENST00000377115 / NM_153675.3; = p.F201V on NM_021784.5) | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FRY | c.1299C>G p.I433M | Missense Mutation (SNP) | VAF 26/351 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FSHR | c.1490del p.A497Vfs*16 | Frame Shift Del (DEL) | VAF 54/379 reads (14%) | called by mutect2, pindel, varscan2
- FYCO1 | c.2028G>C p.Q676H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GDPD1 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GFPT1 | c.413G>C p.S138T | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.122); called by muse, mutect2
- GOLGB1 | c.6181G>C p.E2061Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- GOLGB1 | c.5746G>A p.E1916K | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); called by muse, mutect2
- GPAM | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GRIK3 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GSDMD | c.174C>A p.N58K | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- GSTO2 | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GTF2H4 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HBG2 | c.285C>A p.D95E | Missense Mutation (SNP) | VAF 67/1101 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.067); called by muse, mutect2
- HCST | c.109+5C>G | Splice Region (SNP) | VAF 33/224 reads (15%) | called by muse, mutect2, varscan2
- HEATR6 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- HES1 | c.209C>G p.S70W | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HHEX | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- HMMR | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HNRNPD | c.751A>C p.K251Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- HOXB5 | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA8 | c.1661A>C p.E554A | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); called by muse, mutect2
- HSPG2 | c.1210A>T p.M404L | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ICAM5 | c.1954G>T p.G652C | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGFBP2 | c.424A>T p.S142C | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.171C>G p.C57W | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IGLV9-49 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INSR | c.3040G>C p.D1014H | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS1 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ITGA2B | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 51/382 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ITIH1 | c.954_956del p.I318_L319delinsM | In Frame Del (DEL) | VAF 14/128 reads (11%) | called by mutect2, pindel
- ITPKC | c.1510C>G p.P504A | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ITPRID1 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.116); called by muse, mutect2
- KCNJ6 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNK12 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIFC2 | c.403A>T p.R135W | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- KLF14 | c.743C>A p.T248K | Missense Mutation (SNP) | VAF 50/398 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLF2 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- KLHL35 | c.475C>G p.R159G | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- KYNU | c.282G>T p.W94C | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- LGALS9C | c.686T>A p.I229N | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- LRIG1 | c.1995T>A p.D665E | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRIG3 | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.578); called by muse, mutect2
- LRIT1 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC7 | c.2537G>T p.R846M (on ENST00000651989 / NM_001370785.2; = p.R813M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRIQ3 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- LRRTM4 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LXN | c.445T>A p.W149R | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LY6E | c.162T>A p.S54R | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- MAGEL2 | c.3304G>T p.A1102S | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MAGEL2 | c.165G>T p.L55F | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MAP2 | c.2314G>T p.V772L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MARK4 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MEFV | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MFHAS1 | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MGAT2 | c.671_672del p.E224Gfs*61 | Frame Shift Del (DEL) | VAF 56/528 reads (11%) | called by pindel, varscan2
- MICAL2 | c.3201G>C p.K1067N | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MMAA | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MPP6 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2
- MTRF1L | c.524-4C>G | Splice Region (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- MUC4 | c.9730G>C p.G3244R | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- MYH15 | c.4102G>A p.E1368K | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- MYH4 | c.2807T>A p.I936N | Missense Mutation (SNP) | VAF 64/409 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH7B | c.4956G>C p.E1652D | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- MYH8 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 62/432 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- MYO5A | c.456-2A>G p.X152_splice | Splice Site (SNP) | VAF 29/289 reads (10%) | called by muse, mutect2, varscan2
- MYO9A | c.2338G>C p.D780H | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- MYO9B | c.4275G>C p.K1425N | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MYOM1 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- NBAS | c.5827G>C p.E1943Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NBEA | c.6815C>A p.S2272* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- NDRG1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 64/432 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- NEUROD4 | c.646C>A p.H216N | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEUROD6 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NF1 | c.6016C>G p.L2006V (on ENST00000358273 / NM_001042492.3; = p.L1985V on NM_000267.3) | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NLRP14 | c.3013G>C p.D1005H | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2
- NOTCH1 | c.1131C>G p.I377M | Missense Mutation (SNP) | VAF 57/751 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2
- NPY5R | c.434A>G p.H145R | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2
- NRCAM | c.2740A>C p.M914L (on ENST00000379028 / NM_001371124.1; = p.M898L on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/501 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NRXN2 | c.3264G>T p.Q1088H | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2
- NSUN7 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 27/211 reads (13%) | called by muse, mutect2, varscan2
- NT5C1B | c.1669C>G p.L557V (on ENST00000359846 / NM_001199086.2; = p.L497V on NM_033253.4) | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- OCM2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.056); called by muse, varscan2
- OR5T1 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.119); called by muse, mutect2
- OR8B2 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- OR8D1 | c.537T>A p.C179* | Nonsense Mutation (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- OTOS | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- P3H3 | c.1402G>T p.V468L | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.6); called by muse, mutect2
- PAQR3 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDHA2 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2
- PGRMC2 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- PKP2 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PLCXD3 | c.965G>T p.*322Lext*1 | Nonstop Mutation (SNP) | VAF 13/180 reads (7%) | called by muse, mutect2
- PLD5 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PLEKHA7 | c.3026G>T p.S1009I | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PPP1R27 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF17 | c.1108C>A p.L370M | Missense Mutation (SNP) | VAF 80/489 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PRAMEF17 | c.1109T>A p.L370Q | Missense Mutation (SNP) | VAF 81/495 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PRMT5 | c.420C>G p.N140K | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PRORP | c.1395G>T p.K465N | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRRC2B | c.1826G>C p.R609T | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PTCRA | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PUM2 | c.3166A>G p.I1056V | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASAL2 | c.1934G>T p.G645V | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- RASGRP3 | c.646del p.Q216Sfs*26 | Frame Shift Del (DEL) | VAF 20/166 reads (12%) | called by pindel, varscan2
- RASIP1 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 31/237 reads (13%) | called by muse, mutect2, varscan2
- RAX2 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 68/433 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- RBFOX3 | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RESF1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.147); called by muse, mutect2
- RPS6KB2 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.05); called by muse, mutect2
- RYR2 | c.2449C>A p.P817T | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- SACM1L | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SALL1 | c.2218G>T p.G740C | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SCN11A | c.2597A>G p.Q866R | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SENP7 | c.3088C>T p.R1030W | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERAC1 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SETD2 | c.2918G>C p.R973T | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SGCD | c.865C>A p.L289I (on ENST00000435422 / NM_001128209.2; = p.L290I on NM_000337.5) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SH2B2 | c.1332G>C p.E444D | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, varscan2
- SH3TC1 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SHANK1 | c.2711del p.P904Qfs*3 | Frame Shift Del (DEL) | VAF 49/314 reads (16%) | called by mutect2, pindel, varscan2
- SHANK3 | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2
- SLC12A1 | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- SLC29A4 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2
- SLC9A2 | c.425del p.F142Sfs*34 | Frame Shift Del (DEL) | VAF 21/206 reads (10%) | called by mutect2, pindel
- SLC9A9 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 34/236 reads (14%) | called by muse, mutect2, varscan2
- SLITRK6 | c.1944G>A p.M648I | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMG7 | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SNRPN | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SORCS1 | c.2444A>T p.H815L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2
- SPOP | c.984T>A p.H328Q | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- STON2 | c.1286C>T p.S429L (on ENST00000649389 / NM_001366849.2; = p.S372L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- SYT16 | c.1346T>A p.M449K | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TAF2 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); called by muse, mutect2
- TECTA | c.3810G>T p.W1270C | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TEX45 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); called by muse, mutect2
- THSD7B | c.2314G>T p.A772S | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- TIGD2 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TJP3 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- TMPRSS3 | c.205+1G>A p.X69_splice | Splice Site (SNP) | VAF 19/215 reads (9%) | called by muse, mutect2
- TNFRSF1A | c.1229G>T p.R410L | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TNIP2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TOP3A | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.074); called by muse, varscan2
- TRANK1 | c.5889A>T p.E1963D | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRDN | c.1519G>T p.V507F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- TRPV6 | c.707_715del p.G236_T238del | In Frame Del (DEL) | VAF 18/165 reads (11%) | called by mutect2, pindel
- TSG101 | c.357+1G>T p.X119_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- TSHR | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPOAP1 | c.1333G>T p.A445S | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- TTLL8 | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.81142G>C p.E27048Q (on ENST00000591111; = p.E19624Q on NM_003319.4) | Missense Mutation (SNP) | VAF 25/142 reads (18%) | PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TTN | c.29434G>T p.G9812C (on ENST00000591111; = p.G8885C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/177 reads (14%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TXNDC11 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TYK2 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 63/500 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- UBQLN3 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2
- UGT2B11 | c.1091-1G>T p.X364_splice | Splice Site (SNP) | VAF 30/197 reads (15%) | called by muse, mutect2, varscan2
- VAT1L | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- VPS45 | c.438+7A>T | Splice Region (SNP) | VAF 56/194 reads (29%) | called by muse, mutect2, varscan2
- VWA3B | c.1883C>G p.P628R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR47 | c.1309C>T p.Q437* (on ENST00000369962 / NM_001142551.2; = p.Q438* on NM_014969.5) | Nonsense Mutation (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- WDR64 | c.2020T>A p.W674R | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZFP82 | c.1111T>C p.C371R | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFR | c.2298G>C p.E766D | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZHX2 | c.1722C>A p.D574E | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF208 | c.3388A>T p.K1130* | Nonsense Mutation (SNP) | VAF 46/305 reads (15%) | called by muse, mutect2, varscan2
- ZNF211 | c.1444G>A p.E482K (on ENST00000347302 / NM_198855.4; = p.E495K on NM_006385.5) | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- ZNF391 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | called by muse, varscan2
- ZNF407 | c.5788C>A p.L1930I | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF436 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZNF547 | c.652G>T p.G218W | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF70 | c.321C>G p.I107M | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF777 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZSCAN31 | c.768G>T p.E256D | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ADAM17 | c.687G>A p.V229= | Silent (SNP) | VAF 13/147 reads (9%) | called by muse, mutect2
- ADAMTS6 | c.1035T>C p.N345= | Silent (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.951C>T p.F317= | Silent (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2, varscan2
- ADAR | c.2979G>A p.E993= | Silent (SNP) | VAF 49/443 reads (11%) | catalogued as rs745580283; called by muse, mutect2, varscan2
- AGBL5 | c.1863C>T p.P621= | Silent (SNP) | VAF 26/231 reads (11%) | called by muse, mutect2, varscan2
- ALK | c.2076G>A p.G692= | Silent (SNP) | VAF 46/382 reads (12%) | catalogued as COSV101202913; called by muse, mutect2, varscan2
- ANAPC1 | c.5787G>C p.L1929= | Silent (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- ANKUB1 | c.1041G>C p.V347= | Silent (SNP) | VAF 36/416 reads (9%) | called by muse, mutect2
- ARFGAP1 | c.54G>A p.E18= | Silent (SNP) | VAF 24/211 reads (11%) | catalogued as rs777790138, COSV62263919; called by muse, mutect2, varscan2
- ARHGEF17 | c.3394C>A p.R1132= | Silent (SNP) | VAF 23/408 reads (6%) | called by muse, mutect2
- ATP2B3 | c.1935C>T p.T645= | Silent (SNP) | VAF 31/150 reads (21%) | called by muse, mutect2, varscan2
- ATP6V1FNB | c.498C>T p.F166= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs968302900; called by muse, mutect2
- BAX | c.336C>A p.A112= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- BAZ2A | c.5346C>G p.L1782= | Silent (SNP) | VAF 36/372 reads (10%) | catalogued as rs771409057; called by muse, mutect2
- C2orf49 | c.162C>T p.V54= | Silent (SNP) | VAF 12/199 reads (6%) | called by muse, mutect2
- CACNA2D4 | c.1611G>C p.L537= | Silent (SNP) | VAF 34/222 reads (15%) | called by muse, mutect2, varscan2
- CDC42BPG | c.24G>A p.L8= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, varscan2
- CELSR1 | c.6777G>C p.T2259= | Silent (SNP) | VAF 22/183 reads (12%) | called by muse, mutect2, varscan2
- CHERP | c.846G>A p.Q282= | Silent (SNP) | VAF 28/300 reads (9%) | called by muse, mutect2
- CHRD | c.915C>G p.L305= | Silent (SNP) | VAF 23/248 reads (9%) | catalogued as COSV99200738; called by muse, mutect2
- CILP2 | c.777C>T p.I259= | Silent (SNP) | VAF 48/492 reads (10%) | called by muse, mutect2
- CNTNAP5 | c.3636G>T p.T1212= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV70493671; called by muse, mutect2
- COL13A1 | c.223C>T p.L75= | Silent (SNP) | VAF 56/410 reads (14%) | called by muse, mutect2, varscan2
- COLEC12 | c.489C>A p.L163= | Silent (SNP) | VAF 10/194 reads (5%) | catalogued as COSV68373110; called by muse, mutect2
- CPS1 | c.1401A>T p.A467= | Silent (SNP) | VAF 64/314 reads (20%) | catalogued as rs769809767; called by muse, mutect2, varscan2
- CR1 | c.3216C>T p.I1072= | Silent (SNP) | VAF 67/420 reads (16%) | catalogued as rs778905839; called by muse, mutect2, varscan2
- CSMD2 | c.4098C>T p.F1366= | Silent (SNP) | VAF 35/261 reads (13%) | catalogued as COSV53889617; called by muse, mutect2, varscan2
- CUBN | c.6036T>A p.A2012= | Silent (SNP) | VAF 38/304 reads (13%) | called by muse, mutect2, varscan2
- CUBN | c.5523G>C p.T1841= | Silent (SNP) | VAF 33/340 reads (10%) | catalogued as rs767515084, COSV64715543, COSV64717173; called by muse, mutect2, varscan2
- CUL3 | c.111G>A p.L37= | Silent (SNP) | VAF 44/200 reads (22%) | catalogued as rs542286108, COSV100023871; called by muse, mutect2, varscan2
- DIP2A | c.960G>A p.L320= | Silent (SNP) | VAF 22/268 reads (8%) | catalogued as COSV100594997; called by muse, mutect2
- DIP2C | c.3660C>A p.A1220= | Silent (SNP) | VAF 29/291 reads (10%) | catalogued as COSV55145025, COSV55179007; called by muse, mutect2
- DNAH11 | c.4488A>G p.L1496= | Silent (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2
- DOC2A | c.594C>T p.L198= | Silent (SNP) | VAF 46/454 reads (10%) | called by muse, mutect2
- DPPA4 | c.609G>T p.L203= | Silent (SNP) | VAF 106/396 reads (27%) | called by muse, mutect2, varscan2
- EHMT1 | c.1245C>T p.D415= | Silent (SNP) | VAF 56/574 reads (10%) | called by muse, mutect2
- ELFN1 | c.1272C>A p.G424= | Silent (SNP) | VAF 37/383 reads (10%) | called by muse, mutect2, varscan2
- ERVV-2 | c.1416C>A p.L472= | Silent (SNP) | VAF 63/283 reads (22%) | called by muse, mutect2, varscan2
- ESYT1 | c.2691C>T p.L897= | Silent (SNP) | VAF 9/258 reads (3%) | called by muse, mutect2
- F11 | c.390C>T p.A130= | Silent (SNP) | VAF 33/388 reads (9%) | called by muse, mutect2
- FAM205A | c.3393G>A p.E1131= | Silent (SNP) | VAF 36/245 reads (15%) | called by muse, mutect2, varscan2
- FFAR3 | c.87C>T p.L29= | Silent (SNP) | VAF 159/1221 reads (13%) | catalogued as rs1357285605, COSV59909196, COSV59909320; called by muse, mutect2, varscan2
- FREM2 | c.3076T>C p.L1026= | Silent (SNP) | VAF 30/298 reads (10%) | called by muse, mutect2
- GAL3ST3 | c.276G>A p.L92= | Silent (SNP) | VAF 31/308 reads (10%) | called by muse, mutect2, varscan2
- GLIS3 | c.1200G>A p.L400= | Silent (SNP) | VAF 40/316 reads (13%) | catalogued as COSV60927563; called by muse, mutect2, varscan2
- GLYR1 | c.588G>A p.P196= | Silent (SNP) | VAF 32/362 reads (9%) | catalogued as rs772879234, COSV100424525, COSV58926091; called by muse, mutect2
- GNA11 | c.597C>T p.I199= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2, varscan2
- GRM1 | c.1899C>T p.I633= | Silent (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
- GUCY2C | c.3201C>T p.D1067= | Silent (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2
- H4C6 | c.144G>A p.S48= | Silent (SNP) | VAF 31/186 reads (17%) | catalogued as rs572582669, COSV66685439; called by muse, mutect2, varscan2
- HDAC10 | c.1311G>C p.L437= | Silent (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- HMCN1 | c.12639A>G p.L4213= | Silent (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- HSF1 | c.549G>A p.Q183= | Silent (SNP) | VAF 41/341 reads (12%) | called by muse, mutect2, varscan2
- HTRA4 | c.306C>T p.F102= | Silent (SNP) | VAF 21/167 reads (13%) | called by muse, mutect2, varscan2
- ISL1 | c.511C>A p.R171= | Silent (SNP) | VAF 49/416 reads (12%) | catalogued as COSV57933789; called by muse, mutect2
- KANK2 | c.600G>A p.R200= | Silent (SNP) | VAF 28/191 reads (15%) | catalogued as rs781691425; called by muse, mutect2, varscan2
- KCNA5 | c.1308G>A p.L436= | Silent (SNP) | VAF 76/521 reads (15%) | called by muse, mutect2, varscan2
- KCNT2 | c.3240C>A p.L1080= | Silent (SNP) | VAF 49/195 reads (25%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.741C>A p.A247= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs781455982; called by muse, mutect2, varscan2
- KIAA1143 | c.159A>G p.E53= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as rs1384099034; called by muse, mutect2, varscan2
- KIF26A | c.4008G>C p.L1336= | Silent (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- KIF2B | c.624C>A p.P208= | Silent (SNP) | VAF 43/268 reads (16%) | called by muse, mutect2, varscan2
- KLHL1 | c.1443G>A p.L481= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as COSV100917332; called by muse, mutect2, varscan2
- LANCL1 | c.153G>A p.L51= | Silent (SNP) | VAF 24/214 reads (11%) | called by muse, mutect2
- LDLRAP1 | c.270G>A p.L90= | Silent (SNP) | VAF 59/470 reads (13%) | called by muse, mutect2, varscan2
- LHFPL3 | c.51G>T p.R17= | Silent (SNP) | VAF 59/487 reads (12%) | called by muse, varscan2
- LIPH | c.465A>T p.L155= | Silent (SNP) | VAF 26/274 reads (9%) | called by muse, mutect2
- LPIN1 | c.435G>A p.T145= | Silent (SNP) | VAF 44/411 reads (11%) | catalogued as COSV99877222; called by muse, mutect2, varscan2
- LRRC4C | c.123G>C p.L41= | Silent (SNP) | VAF 18/294 reads (6%) | catalogued as COSV99537515; called by muse, mutect2
- LRRC8C | c.2256A>G p.L752= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs1252296372; called by muse, mutect2, varscan2
- LRRTM4 | c.354C>A p.S118= | Silent (SNP) | VAF 30/157 reads (19%) | catalogued as COSV69143207; called by muse, mutect2, varscan2
- MALSU1 | c.9G>T p.P3= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as rs774453191; called by muse, mutect2, varscan2
- MAP3K20 | c.345C>T p.A115= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- MAP4K1 | c.693C>A p.G231= | Silent (SNP) | VAF 65/353 reads (18%) | called by muse, mutect2, varscan2
- MCAM | c.60C>G p.R20= | Silent (SNP) | VAF 66/553 reads (12%) | called by muse, mutect2, varscan2
- MCOLN1 | c.936C>T p.S312= | Silent (SNP) | VAF 70/515 reads (14%) | called by muse, mutect2, varscan2
- MFAP3L | c.924G>T p.L308= | Silent (SNP) | VAF 33/238 reads (14%) | called by muse, mutect2, varscan2
- MRPL40 | c.27C>T p.I9= | Silent (SNP) | VAF 24/304 reads (8%) | catalogued as rs781030757; called by muse, mutect2
- NAV2 | c.1221C>G p.P407= (on ENST00000396087 / NM_001244963.2; = p.P384= on NM_145117.5) | Silent (SNP) | VAF 4/37 reads (11%) | called by mutect2, varscan2
- NAV3 | c.5343G>T p.V1781= | Silent (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- NDN | c.531C>T p.D177= | Silent (SNP) | VAF 34/395 reads (9%) | called by muse, mutect2
- NKAPD1 | c.738T>G p.T246= (on ENST00000280352 / NM_001082970.2; = p.T247= on NM_018195.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/150 reads (13%) | called by muse, mutect2, varscan2
- NLRP5 | c.3531C>T p.L1177= | Silent (SNP) | VAF 60/290 reads (21%) | catalogued as COSV66764533; called by muse, mutect2, varscan2
- NSFL1C | c.1014C>A p.I338= | Silent (SNP) | VAF 26/185 reads (14%) | called by muse, mutect2, varscan2
- NT5C1B | c.1032C>T p.N344= (on ENST00000359846 / NM_001199086.2; = p.N284= on NM_033253.4) | Silent (SNP) | VAF 58/664 reads (9%) | catalogued as rs1219765669, COSV58394446; called by muse, mutect2
- NUP93 | c.315G>A p.E105= | Silent (SNP) | VAF 19/226 reads (8%) | called by muse, mutect2
- ONECUT1 | c.1191T>G p.R397= | Silent (SNP) | VAF 57/324 reads (18%) | called by muse, mutect2, varscan2
- OR10A2 | c.561C>T p.I187= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as rs144699545; called by muse, mutect2, varscan2
- OR1C1 | c.579C>A p.S193= | Silent (SNP) | VAF 38/213 reads (18%) | called by muse, mutect2, varscan2
- OR2Z1 | c.501C>T p.P167= | Silent (SNP) | VAF 24/311 reads (8%) | catalogued as COSV100136512; called by muse, mutect2
- OR5AS1 | c.483C>T p.C161= | Silent (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- OR8G1 | c.723T>C p.C241= | Silent (SNP) | VAF 32/247 reads (13%) | called by muse, mutect2, varscan2
- OTUD7B | c.2502G>C p.P834= | Silent (SNP) | VAF 42/148 reads (28%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1002C>T p.I334= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV53896761; called by muse, mutect2, varscan2
- PDE6C | c.1434T>C p.N478= | Silent (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- PDHB | c.90G>A p.A30= | Silent (SNP) | VAF 73/450 reads (16%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1431G>A p.Q477= | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as COSV67314329; called by muse, mutect2, varscan2
- PIAS2 | c.118A>C p.R40= | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as COSV61344169; called by muse, mutect2
- PIK3CB | c.2100G>C p.R700= | Silent (SNP) | VAF 11/195 reads (6%) | called by muse, mutect2
- PNLIPRP1 | c.516G>C p.L172= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as COSV100724185, COSV100724502; called by muse, mutect2, varscan2
- POTEA | c.324C>A p.A108= | Silent (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- PPP1R14B | c.51C>A p.P17= | Silent (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2
- PRDM4 | c.510G>A p.V170= | Silent (SNP) | VAF 46/237 reads (19%) | called by muse, mutect2, varscan2
- PRX | c.303C>A p.P101= | Silent (SNP) | VAF 77/741 reads (10%) | called by muse, mutect2, varscan2
- PTPN18 | c.147G>T p.V49= | Silent (SNP) | VAF 23/151 reads (15%) | called by muse, mutect2, varscan2
- RBM10 | c.2724C>T p.V908= | Silent (SNP) | VAF 44/262 reads (17%) | called by mutect2, varscan2
- REG3A | c.411C>A p.P137= | Silent (SNP) | VAF 13/181 reads (7%) | catalogued as COSV100532923; called by muse, mutect2
- RNF125 | c.657C>T p.D219= | Silent (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- ROGDI | c.565C>T p.L189= | Silent (SNP) | VAF 36/446 reads (8%) | called by muse, mutect2
- RUSF1 | c.1158G>T p.L386= | Silent (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- SECTM1 | c.258C>T p.F86= | Silent (SNP) | VAF 79/511 reads (15%) | called by muse, mutect2, varscan2
- SETX | c.4749C>T p.G1583= | Silent (SNP) | VAF 115/409 reads (28%) | catalogued as rs946753089; called by muse, mutect2, varscan2
- SH3BP4 | c.2148C>A p.T716= | Silent (SNP) | VAF 34/181 reads (19%) | called by muse, mutect2, varscan2
- SLC15A2 | c.450G>C p.L150= | Silent (SNP) | VAF 12/117 reads (10%) | called by mutect2, varscan2
- SLC16A2 | c.1341C>A p.A447= | Silent (SNP) | VAF 46/177 reads (26%) | called by muse, mutect2, varscan2
- SLC35F1 | c.468C>A p.T156= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- SLC45A4 | c.2067G>T p.V689= (on ENST00000517878 / NM_001286646.2; = p.V638= on NM_001080431.2) | Silent (SNP) | VAF 41/386 reads (11%) | catalogued as COSV50140850; called by muse, mutect2, varscan2
- SLC9A2 | c.120G>A p.P40= | Silent (SNP) | VAF 35/316 reads (11%) | catalogued as COSV52134842; called by muse, mutect2, varscan2
- SLITRK3 | c.508C>A p.R170= | Silent (SNP) | VAF 37/218 reads (17%) | catalogued as COSV53853476; called by muse, mutect2, varscan2
- SLITRK4 | c.450C>A p.A150= | Silent (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- SNAPC4 | c.2829G>T p.P943= | Silent (SNP) | VAF 58/143 reads (41%) | catalogued as COSV100047703; called by muse, mutect2, varscan2
- SNX15 | c.339C>G p.L113= | Silent (SNP) | VAF 27/253 reads (11%) | catalogued as COSV57247466; called by muse, mutect2
- SSX1 | c.6C>T p.N2= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs781970984, COSV65356457; called by muse, mutect2, varscan2
- STYXL2 | c.2646G>T p.V882= | Silent (SNP) | VAF 50/190 reads (26%) | called by muse, mutect2, varscan2
- SUCLG1 | c.63C>A p.L21= | Silent (SNP) | VAF 27/191 reads (14%) | catalogued as rs982734922, COSV67265520, COSV67265626; called by muse, mutect2, varscan2
- TBC1D10C | c.1104C>T p.L368= | Silent (SNP) | VAF 74/567 reads (13%) | catalogued as rs770671676; called by muse, mutect2, varscan2
- TCF4 | c.1323T>G p.L441= | Silent (SNP) | VAF 30/272 reads (11%) | called by muse, mutect2, varscan2
- TEX2 | c.3108C>T p.V1036= (on ENST00000583097 / NM_001288733.2; = p.V1043= on NM_018469.5) | Silent (SNP) | VAF 42/263 reads (16%) | catalogued as rs1170199593; called by muse, mutect2, varscan2
- TG | c.378C>T p.Y126= | Silent (SNP) | VAF 54/536 reads (10%) | catalogued as rs774013491, CM130234, COSV55091696; called by muse, mutect2
- TGM6 | c.924G>A p.L308= | Silent (SNP) | VAF 15/438 reads (3%) | catalogued as COSV99171666; called by muse, mutect2
- TNNT2 | c.678G>A p.R226= (on ENST00000236918; = p.R223= on NM_000364.4) | Silent (SNP) | VAF 159/603 reads (26%) | called by muse, mutect2, varscan2
- TNRC18 | c.1482C>T p.F494= | Silent (SNP) | VAF 62/543 reads (11%) | catalogued as rs777049427, COSV68087306; called by muse, mutect2, varscan2
- TRIM59 | c.1038C>G p.L346= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV59087030; called by muse, mutect2, varscan2
- TRNAU1AP | c.54C>T p.F18= | Silent (SNP) | VAF 22/232 reads (9%) | catalogued as rs1292176784; called by muse, mutect2
- TRPM4 | c.2937C>T p.P979= | Silent (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- TSHZ2 | c.2319G>A p.K773= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV61589086; called by muse, mutect2, varscan2
- TUB | c.1353C>T p.S451= (on ENST00000299506 / NM_177972.3; = p.S506= on NM_003320.4) | Silent (SNP) | VAF 24/186 reads (13%) | catalogued as rs770012408; called by muse, mutect2, varscan2
- TULP3 | c.643C>A p.R215= | Silent (SNP) | VAF 33/300 reads (11%) | catalogued as COSV101237552; called by muse, mutect2, varscan2
- UBE2G2 | c.264C>G p.V88= | Silent (SNP) | VAF 8/179 reads (4%) | catalogued as COSV58368764; called by muse, mutect2
- UNC13D | c.1800G>A p.T600= | Silent (SNP) | VAF 56/404 reads (14%) | catalogued as rs751827268; called by muse, mutect2, varscan2
- UPF1 | c.1665C>G p.L555= (on ENST00000599848 / NM_001297549.2; = p.L544= on NM_002911.4) | Silent (SNP) | VAF 34/402 reads (8%) | called by muse, mutect2
- VSTM2B | c.678G>T p.T226= | Silent (SNP) | VAF 95/480 reads (20%) | catalogued as rs1305799424; called by muse, mutect2, varscan2
- WDFY3 | c.2511A>G p.S837= | Silent (SNP) | VAF 15/176 reads (9%) | called by muse, mutect2
- WNK2 | c.4425G>A p.E1475= (on ENST00000297954 / NM_001282394.1; = p.E1438= on NM_006648.3) | Silent (SNP) | VAF 35/220 reads (16%) | catalogued as rs1246511837, COSV52938895; called by muse, mutect2, varscan2
- XIRP2 | c.1293A>G p.Q431= (on ENST00000628543; = p.Q606= on NM_152381.6) | Silent (SNP) | VAF 24/227 reads (11%) | catalogued as COSV54717406; called by muse, mutect2, varscan2
- ZNF19 | c.1068C>T p.P356= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- ZNF726 | c.1491T>G p.T497= | Silent (SNP) | VAF 55/427 reads (13%) | called by muse, mutect2, varscan2
- ZNF727 | c.123C>T p.F41= | Silent (SNP) | VAF 21/170 reads (12%) | catalogued as COSV101473385; called by muse, mutect2, varscan2
- ZNF746 | c.1785G>T p.P595= | Silent (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2, varscan2
- ZNF80 | c.165G>C p.G55= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs767523471; called by muse, mutect2, varscan2
- ZNF827 | c.1083C>T p.P361= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs761641974; called by muse, mutect2
- ZNF98 | c.906T>A p.A302= | Silent (SNP) | VAF 11/59 reads (19%) | called by mutect2, varscan2
- ABCA3 | c.3863-43G>T | Intron (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- AC092329.3 | c.-211-447G>T | Intron (SNP) | VAF 30/271 reads (11%) | called by muse, mutect2, varscan2
- AC099552.1 | n.172C>T | RNA (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2
- ADD3-AS1 | n.6102T>A | RNA (SNP) | VAF 25/330 reads (8%) | called by muse, mutect2
- ADGB | c.4818+5466C>T | Intron (SNP) | VAF 33/287 reads (11%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498877 T>C | 5'Flank (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- AREL1 | c.-252C>G | 5'UTR (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.367+11G>T | Intron (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- ATP5PF | c.-91A>G | 5'UTR (SNP) | VAF 27/340 reads (8%) | catalogued as rs1455819076; called by muse, mutect2
- AZGP1 | chr7:99980845 G>C | 5'Flank (SNP) | VAF 37/338 reads (11%) | called by muse, mutect2, varscan2
- C4orf17 | c.*26C>T | 3'UTR (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- C4orf3 | chr4:119300726 C>G | 5'Flank (SNP) | VAF 7/59 reads (12%) | catalogued as rs1197511187; called by muse, mutect2, varscan2
- CCL7 | c.-16G>T | 5'UTR (SNP) | VAF 31/229 reads (14%) | called by muse, mutect2, varscan2
- CREB5 | chr7:28410229 G>T | 5'Flank (SNP) | VAF 72/284 reads (25%) | called by muse, mutect2, varscan2
- DOCK5 | c.3816+51C>T | Intron (SNP) | VAF 32/256 reads (13%) | called by muse, mutect2, varscan2
- ELF2 | c.239-10584G>C | Intron (SNP) | VAF 34/302 reads (11%) | called by muse, mutect2, varscan2
- EML2 | chr19:45642290 G>C | 5'Flank (SNP) | VAF 54/251 reads (22%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445653 C>T | 3'Flank (SNP) | VAF 48/298 reads (16%) | catalogued as rs1258578446; called by muse, mutect2, varscan2
- FAM27E5 | n.394C>G | RNA (SNP) | VAF 41/348 reads (12%) | called by muse, mutect2, varscan2
- FBRS | chr16:30662415 C>G | 5'Flank (SNP) | VAF 17/238 reads (7%) | called by muse, mutect2
- FRYL | c.-6A>G | 5'UTR (SNP) | VAF 29/193 reads (15%) | catalogued as rs1385672876; called by muse, mutect2, varscan2
- GABPB1 | c.-1+304C>G | Intron (SNP) | VAF 33/245 reads (13%) | catalogued as rs901272790; called by muse, mutect2, varscan2
- HAGHL | c.*352C>G | 3'UTR (SNP) | VAF 56/425 reads (13%) | called by muse, mutect2, varscan2
- HCN1 | c.-6C>A | 5'UTR (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- HMGB1P1 | n.322G>C | RNA (SNP) | VAF 72/262 reads (27%) | called by muse, mutect2, varscan2
- HOXA10 | c.*179G>C | 3'UTR (SNP) | VAF 48/604 reads (8%) | catalogued as rs1376894847; called by muse, mutect2
- HSPA7 | n.51C>A | RNA (SNP) | VAF 93/479 reads (19%) | called by muse, mutect2, varscan2
- IGFBP1 | c.-11C>T | 5'UTR (SNP) | VAF 45/395 reads (11%) | called by muse, mutect2, varscan2
- IL15RA | c.89-2486G>A | Intron (SNP) | VAF 86/386 reads (22%) | called by muse, mutect2, varscan2
- IL6R | c.949+1420C>T | Intron (SNP) | VAF 61/175 reads (35%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.2413-2775T>A | Intron (SNP) | VAF 45/210 reads (21%) | called by muse, varscan2
- KRT7 | chr12:52252315 G>C | 3'Flank (SNP) | VAF 76/648 reads (12%) | called by mutect2, varscan2
- LYSMD3 | c.-79C>G | 5'UTR (SNP) | VAF 53/427 reads (12%) | catalogued as rs955036144; called by muse, mutect2, varscan2
- MASP1 | c.1304-4272A>G | Intron (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- MCRIP1 | c.-48-1738G>T | Intron (SNP) | VAF 37/248 reads (15%) | catalogued as rs1030211179; called by muse, mutect2, varscan2
- METTL6 | c.532-663C>A | Intron (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- MMP28 | c.1169-125G>T | Intron (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- MS4A2 | c.*42C>T | 3'UTR (SNP) | VAF 27/216 reads (13%) | called by muse, mutect2, varscan2
- NBEA | c.*4T>A | 3'UTR (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- NCF1 | c.906-34C>T | Intron (SNP) | VAF 32/259 reads (12%) | catalogued as rs587711972; called by muse, mutect2, varscan2
- NDUFA6 | chr22:42090870 G>A | 5'Flank (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- NEDD4 | c.-25T>C | 5'UTR (SNP) | VAF 42/261 reads (16%) | catalogued as rs1309379902; called by muse, mutect2, varscan2
- NPSR1 | c.1026-239T>A | Intron (SNP) | VAF 25/184 reads (14%) | called by muse, mutect2, varscan2
- NUP62 | c.*653C>G | 3'UTR (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- OR2L1P | n.802C>A | RNA (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- OR56B3P | n.575C>T | RNA (SNP) | VAF 24/310 reads (8%) | called by muse, mutect2
- PIDD1 | c.2275-19C>T | Intron (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- PLEKHJ1 | c.94+50G>C | Intron (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.331-380C>A | Intron (SNP) | VAF 33/283 reads (12%) | catalogued as rs782191859; called by muse, mutect2, varscan2
- POM121 | chr7:72948460 G>A | 3'Flank (SNP) | VAF 51/782 reads (7%) | catalogued as rs149749986; called by muse, mutect2
- PPP1R9A | c.2757+786T>A | Intron (SNP) | VAF 22/177 reads (12%) | catalogued as rs1198435104; called by muse, mutect2, varscan2
- PRKAR1A | c.974-35G>A | Intron (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- RPL23A | c.26-328C>T | Intron (SNP) | VAF 20/172 reads (12%) | called by muse, mutect2, varscan2
- RRM2 | chr2:10122689 G>T | 5'Flank (SNP) | VAF 17/205 reads (8%) | called by muse, mutect2
- RTL1 | chr14:100875080 G>T | 3'Flank (SNP) | VAF 37/174 reads (21%) | called by muse, mutect2, varscan2
- SCGB3A1 | c.*4G>A | 3'UTR (SNP) | VAF 63/329 reads (19%) | catalogued as rs368634887; called by muse, mutect2, varscan2
- SEMA4D | chr9:89376984 G>A | 3'Flank (SNP) | VAF 45/303 reads (15%) | called by muse, mutect2, varscan2
- SLC16A7 | c.217+28762A>T | Intron (SNP) | VAF 47/267 reads (18%) | called by muse, mutect2, varscan2
- SNORA71B | n.152C>T | RNA (SNP) | VAF 31/172 reads (18%) | catalogued as rs746756758; called by muse, mutect2, varscan2
- SORBS2 | c.-46+1117G>C | Intron (SNP) | VAF 37/289 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.1400T>A | RNA (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- SSPOP | n.5885G>T | RNA (SNP) | VAF 32/255 reads (13%) | called by muse, mutect2, varscan2
- SWAP70 | c.-46G>A | 5'UTR (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2
- TMEM191B | c.547-10C>T | Intron (SNP) | VAF 14/120 reads (12%) | called by mutect2, varscan2
- TRHR | c.*28A>G | 3'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- TTC38 | c.616-1408G>A | Intron (SNP) | VAF 14/216 reads (6%) | catalogued as rs1025241309; called by muse, mutect2
- UMPS | c.*558C>T | 3'UTR (SNP) | VAF 15/99 reads (15%) | catalogued as COSV51739509; called by muse, mutect2, varscan2
- ZNF414 | chr19:8510723 C>T | 3'Flank (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
